Somatic mutation profile of tumor specimen ALCH-B1N0-TTP1-A (aliquot ALCH-B1N0-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1N0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.8 years (21,838 days).
Specimen ALCH-B1N0-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4404ad20-429f-424a-811c-4818a33aa313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1N0-NB1-A (Blood Derived Normal), aliquot ALCH-B1N0-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7a87088-1e20-41ed-9c2b-ab180fa0ba81

The open-access MAF lists 24 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 6, Splice Site 2, 5'UTR 2, Nonsense Mutation 2, Intron 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 212/714 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 86/456 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373329783; called by muse, mutect2, varscan2
- FANK1 | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 37/573 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1216512087, COSV64156765, COSV64157144; called by muse, mutect2
- SAGE1 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 14/256 reads (5%) | catalogued as rs781867792, COSV61016921; called by muse, mutect2
- SYP | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV54294786; called by muse, mutect2
- TP53I13 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 16/159 reads (10%) | catalogued as rs777746924, CM142645; called by muse, mutect2, varscan2
- ZFAND2B | c.682T>G p.L228V | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs11555993; called by muse, mutect2
- ASB8 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.068); called by muse, mutect2
- CFB | c.1956+2T>G p.X652_splice | Splice Site (SNP) | VAF 37/732 reads (5%) | called by muse, mutect2
- NLRP12 | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- PLXNA2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- ZNF230 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- BTNL8 | c.1107G>A p.V369= | Silent (SNP) | VAF 33/471 reads (7%) | called by muse, mutect2
- CEP192 | c.564A>G p.L188= | Silent (SNP) | VAF 32/257 reads (12%) | catalogued as rs1324444858; called by muse, mutect2, varscan2
- CREM | c.876G>A p.R292= (on ENST00000429130; = p.R247= on NM_181571.3) | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- EYA2 | c.1374C>T p.V458= | Silent (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- PANK4 | c.297C>G p.T99= | Silent (SNP) | VAF 42/842 reads (5%) | called by muse, mutect2
- TENM1 | c.6346C>T p.L2116= | Silent (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 6/14 reads (43%) | catalogued as rs190105354; called by muse, varscan2
- RBM44 | c.-98-2316G>T | Intron (SNP) | VAF 13/110 reads (12%) | catalogued as rs535325307; called by muse, mutect2, varscan2
- SHMT2 | c.-1G>A | 5'UTR (SNP) | VAF 10/255 reads (4%) | catalogued as COSV100196942; called by muse, mutect2
- SPTLC2 | c.-4G>A | 5'UTR (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- TMEM135 | c.*7333A>G | 3'UTR (SNP) | VAF 30/338 reads (9%) | called by muse, mutect2
